CCDI case PBCRIE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cc3f48d1-5e75-4d37-b6cc-884ec5c8a20a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,208 days).

Biospecimens (3 samples)
- Sample 0DXAQI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXAQP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXAR2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
